Gene-level copy-number profile of tumor specimen ALCH-B34S-TTP1-A from ALCHEMIST case ALCH-B34S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.4 years (26,081 days).
Specimen ALCH-B34S-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 54142416-9330-4f9f-9fa2-13fdec93bcb9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B34S-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/9833a334-4004-4eaa-bf81-7785fc1f9699

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 63; copy number 1: 4,085; copy number 2: 53,292; copy number 3: 706; copy number 4: 160; copy number 5: 71; copy number 8: 5; copy number 9: 2; copy number 13: 2; copy number 17: 5.

Homozygous deletions (total copy number 0; autosomes only): 63 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:247,294,835–247,331,846, 2 genes: Y_RNA, ZNF496.
- chr4:17,614,641–17,634,105, 1 gene (within-gene range 0–2): MED28.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–2): CRB2.
- chr9:131,021,168–131,021,306, 1 gene (within-gene range 0–2): AL583807.1.
- chr11:77,066,961–77,215,241, 3 genes: CAPN5, OMP, MYO7A.
- chr12:1,917,951–1,922,867, 1 gene (within-gene range 0–1): AC005342.2.
- chr12:3,296,202–3,366,122, 2 genes: AC005865.1, LINC02827.
- chr15:25,189,414–25,257,027, 35 genes (within-gene range 0–1): SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr17:21,284,672–21,419,870, 2 genes: MAP2K3, KCNJ12.
- chr17:45,999,250–45,999,694, 1 gene (within-gene range 0–2): STH.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–2): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr18:48,564,795–48,568,342, 1 gene (within-gene range 0–2): AC048380.2.
- chr22:23,059,415–23,145,021, 4 genes (within-gene range 0–2): RSPH14, GNAZ, Metazoa_SRP, U7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 85 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,849,674–120,914,238, 4 genes, copy number 5 (within-gene range 4–5): AC253572.1, RNVU1-19, PPIAL4A, AC241377.3.
- chr2:196,133,583–196,176,503, 2 genes, copy number 5: STK17B, AC114760.2.
- chr9:136,848,724–136,860,799, 2 genes, copy number 5 (within-gene range 3–5): PHPT1, MAMDC4.
- chr9:137,007,234–137,028,922, 1 gene, copy number 5 (within-gene range 3–5): ABCA2.
- chr9:137,220,247–137,221,581, 1 gene, copy number 8: RNF208.
- chr11:1,947,278–2,001,470, 7 genes, copy number 13–17: MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr17:83,135,734–83,240,804, 3 genes, copy number 8–9 (within-gene range 2–9): AC139099.2, AC139099.1, RPL23AP87.
- chr19:589,881–1,279,244, 51 genes, copy number 5: HCN2, AC005559.1, POLRMT, AC004449.1, FGF22, RNF126, AC004156.1, FSTL3, PRSS57, RPS2P52, PALM, MISP, AC006273.1, LINC01836, PTBP1, MIR4745, PLPPR3, MIR3187, AZU1, PRTN3, ELANE, CFD, MED16, RNU6-9, R3HDM4, KISS1R, ARID3A, AC005379.1, AC005391.1, WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4, SBNO2, STK11, HMGB2P1, CBARP, AC004221.1, ATP5F1D, MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr19:3,976,056–4,039,386, 3 genes, copy number 8: EEF2, SNORD37, PIAS4.
- chr20:35,648,925–35,950,370, 11 genes, copy number 5 (within-gene range 2–5): RBM12, NFS1, ROMO1, RBM39, RPF2P1, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P, RNU6-937P.

Autosomal genes at a single copy (total copy number 1): 3,923. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
